MMRF case MMRF_1455 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/32ff98a4-d8b1-4a33-bd7f-e0f07511f454

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.8 years (20,016 days); ISS stage: I; Days to last known disease status: 1,375 days (3.8 years); Days to last follow up: 1,375 days (3.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 82 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 146 days; Days to treatment end: 146 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 147 days; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 247 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 252 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 155 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.934 mg/dL; Immunoglobulin G 4.76 g/L; Immunoglobulin A 4.72 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.39 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 668 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.48 mmol/L; Albumin 48 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 0.14 mg/dL.
- Day 55 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 5.1 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.46 mmol/L.
- Day 174 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.045 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.048 mg/dL; Immunoglobulin G 3.41 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 6.49 mmol/L.
- Day 237 (ECOG 0): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.564 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.576 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.61 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.68 mmol/L.
- Day 344 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 7.52 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 421: Hemoglobin 7.38 mmol/L; Leukocytes 1.9 ×10⁹/L; Platelets 151 ×10⁹/L.
- Day 526 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 8.06 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.4 mmol/L.
- Day 708 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Immunoglobulin G 6.97 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 4.84 mmol/L.
- Day 890 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.978 mg/dL; Immunoglobulin G 6.01 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.44 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.89 mmol/L.
- Day 987 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 7.27 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 1,169 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 7.29 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 5.7 g/dL; Glucose 5.06 mmol/L.
- Day 1,282 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.51 mmol/L.
- Day 1,375 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.57 mmol/L.

Other clinical attributes
- Day -13: Weight: 83 kg; Height: 172 cm.

Biospecimens (1 sample)
- Sample MMRF_1455_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
